Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7487, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7487-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Location:

Service:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Left frontal lesion diagnosed post seizure.

Specimens Submitted:

1: SP: Left frontal brain lesion

2: SP: Left frontal lobe brain tumor

DIAGNOSIS:

1-2. BRAIN, LEFT FRONTAL LOBE, EXCISION:

-OLIGODENDROGLIOMA, WHO GRADE II. SEE NOTE

NOTE:

-MIB-1 LABELING ACTIVITY IS LOW (LESS THAN 2-3%) ACROSS THE GREAT MAJORITY OF TWO SECTIONS ASSESSED. MICROSCOPIC REGIONS OF HIGHER LEVEL MIB-1 LABELING ACTIVITY ARE PRESENT, BUT SO LIMITED IN EXTENT THAT THEIR SIGNIFICANCE IS NOT CLEAR.

-CYTOGENETIC AND MOLECULAR STUDIES FOR 1p/19q DELETION AND MGMT PROMOTER METHYLATION ARE PENDING AND WILL BE REPORTED SEPARATELY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

MIB-1 (Ki-67)

MIB-1 (Ki-67)

MGMT

RECUT

NEG CONT

IMM RECUT

NEG CONT

IMM RECUT

Gross Description:

1. The specimen is received fresh, labeled "left frontal brain lesion," and consists of two fragments of soft unoriented tissue, 0.6 x 0.4 x 0.2 cm, and 0.6 x 0.5 x 0.3 cm. A touch preparation is made; the remaining specimen is submitted entirely for frozen section.

FSC - specimen, in toto.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

2). The specimen is received fresh labeled "left frontal lobe brain tumor" and contains a portion of brain with a gyral surface measuring 6.4 x 2.2 x 3.8 cm. The specimen is serially sectioned to reveal diffuse thickening of the white matter and an area of hemorrhage. Representative sections are submitted. Photographs are taken.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Left frontal brain lesion

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Left frontal lobe brain tumor

Block	Sect. Site	PCs
9	U	9

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: LEFT FRONTAL BRAIN LESION (FS): MALIGNANT GLIOMA.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a2ab128e-1129-4116-9186-7bb81aba7f65 (TCGA-HW-7487.1AA8B50F-BCE6-4CE5-9922-7A852A1D57EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).